Somatic mutation profile of tumor specimen TCGA-F7-A50G-01A (aliquot TCGA-F7-A50G-01A-11D-A25Y-08) from TCGA case TCGA-F7-A50G, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 66.5 years (24,285 days).
Specimen TCGA-F7-A50G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 064e6788-07ab-4934-b395-1fdee1ae1b48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-A50G-10A (Blood Derived Normal), aliquot TCGA-F7-A50G-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c086bfc-9193-4671-a6e9-c511d9b28fbf

The open-access MAF lists 106 somatic variants for this specimen: 79 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 26, Nonsense Mutation 10, Splice Region 2, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRN | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as rs63750411, CM074264, COSV50009772; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs11575996, CS125161, COSV52681350, COSV52690011, COSV52951377, COSV99391417; called by muse, mutect2, varscan2
- ADGRG4 | c.3785C>T p.T1262I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99796269; called by muse, mutect2, varscan2
- ARHGAP31 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 22/148 reads (15%) | catalogued as rs749661211, COSV51791883; called by muse, mutect2, varscan2
- ARHGEF18 | c.842G>A p.R281Q (on ENST00000359920 / NM_001130955.2; = p.R177Q on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs756589490, COSV60467784; called by muse, mutect2, varscan2
- ATP7B | c.2491G>A p.V831I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs374592960; called by muse, mutect2
- BBS12 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as CM104177, COSV100045054; called by muse, mutect2, varscan2
- BROX | c.1169A>C p.E390A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV100572298; called by muse, mutect2, varscan2
- BSN | c.8542C>T p.R2848W | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766482745, COSV56516838; called by muse, mutect2, varscan2
- CABCOCO1 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57596062; called by muse, mutect2, varscan2
- CACNA1I | c.4998G>A p.M1666I | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1250679776, COSV100360485; called by muse, mutect2
- CALML3 | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV100178867; called by muse, mutect2, varscan2
- CAPZB | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99940161; called by muse, mutect2, varscan2
- CCT6B | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV100030921; called by muse, mutect2, varscan2
- CDCA4 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs372232233; called by muse, mutect2, varscan2
- CPA1 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99163317; called by muse, mutect2, varscan2
- CTNND2 | c.1435C>G p.Q479E | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.014); catalogued as rs1290359541, COSV100479619; called by muse, mutect2, varscan2
- CYP7B1 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775806979, COSV59585812, COSV59593141; ClinVar: uncertain significance; called by muse, mutect2
- DHCR24 | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.65); catalogued as COSV100987836; called by muse, mutect2, varscan2
- DHX32 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs961381093, COSV52938026; called by muse, mutect2
- DNM2 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs781589891, COSV100117734; called by muse, mutect2, varscan2
- DOP1B | c.5743C>T p.R1915* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as rs778603259, COSV101215716; called by muse, mutect2, varscan2
- DSCAML1 | c.2024T>A p.I675N (on ENST00000321322; = p.I615N on NM_020693.4) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100356740; called by muse, mutect2
- DYNC1H1 | c.3427C>T p.H1143Y | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs868078939, COSV100795196; called by muse, mutect2
- EHBP1 | c.800C>G p.S267* | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | catalogued as COSV99861514; called by muse, mutect2, varscan2
- EML4 | c.2332C>G p.Q778E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV100581142; called by muse, mutect2, varscan2
- ERLIN2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs1235728999, COSV99379750; called by muse, varscan2
- FAT3 | c.5395C>T p.R1799* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs868369232, COSV53153553, COSV99965750; called by muse, mutect2, varscan2
- FMN2 | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.67); catalogued as rs1249170432, COSV60432677; called by muse, mutect2
- GALNTL6 | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101560405; called by muse, mutect2, varscan2
- GPR174 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as COSV99338317; called by muse, mutect2, varscan2
- GRIK4 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV70801922, COSV70802789; called by muse, mutect2, varscan2
- GRIN2B | c.3335G>A p.R1112Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.325); catalogued as rs557670363, COSV101663134; ClinVar: likely benign; called by muse, mutect2, varscan2
- HAUS4 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.724); catalogued as COSV52826994, COSV99246774, COSV99247062; called by muse, mutect2, varscan2
- HCN4 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99984050; called by muse, mutect2, varscan2
- HEPACAM2 | c.637G>A p.D213N (on ENST00000394468 / NM_001039372.4; = p.D201N on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100506682; called by muse, mutect2, varscan2
- HSPG2 | c.7075G>A p.D2359N | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV101020999; called by muse, mutect2, varscan2
- KDM6B | c.3366G>T p.E1122D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.918); catalogued as COSV99642044; called by muse, mutect2, varscan2
- KIAA1549 | c.5080G>A p.A1694T | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54309503, COSV99651585; called by muse, mutect2, varscan2
- KIT | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.565); catalogued as COSV99854974; called by muse, mutect2, varscan2
- KLK6 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 15/129 reads (12%) | catalogued as rs377282019, COSV100037783; called by muse, mutect2, varscan2
- LIM2 | c.183G>C p.W61C (on ENST00000596399 / NM_001161748.2; = p.W103C on NM_030657.4) | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV99702430; called by muse, mutect2, varscan2
- LPP | c.1535T>G p.I512S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100448012; called by muse, mutect2, varscan2
- MEF2B | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs368616462; called by muse, mutect2, varscan2
- MEPE | c.738G>C p.E246D | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.761); catalogued as COSV100734978; called by muse, mutect2, varscan2
- MYO3B | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV100511230; called by muse, mutect2, varscan2
- NEO1 | c.2618C>T p.T873M | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs374229611; called by muse, mutect2, varscan2
- NOTCH3 | c.4792G>C p.D1598H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99658317; called by muse, mutect2, varscan2
- PCNX3 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.829); catalogued as COSV100482616; called by muse, mutect2
- PIK3CB | c.1075C>G p.H359D | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100005939, COSV56683219; called by muse, mutect2
- PLCB3 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs367729670, COSV99657067; called by muse, mutect2, varscan2
- PNPT1 | c.16T>C p.Y6H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV99569985, COSV99570091, COSV99570345; called by muse, mutect2, varscan2
- PRB3 | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99685957; called by muse, varscan2
- PRDM16 | c.2876T>G p.I959S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV99578115; called by muse, mutect2, varscan2
- PRKG1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100909024; called by muse, mutect2, varscan2
- PRMT3 | c.1289C>G p.S430* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100424122; called by muse, mutect2, varscan2
- PSD | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs754787010, COSV99193426; called by muse, mutect2, varscan2
- PTPRC | c.344C>G p.S115W | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as COSV100722930; called by muse, mutect2, varscan2
- RELN | c.7182G>A p.A2394= | Splice Region (SNP) | VAF 7/44 reads (16%) | catalogued as rs879182818, COSV100634462; called by muse, mutect2
- RGS22 | c.2121C>G p.F707L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100693012, COSV100693610; called by muse, mutect2, varscan2
- RSPH10B | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 45/336 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs140401316; called by muse, mutect2
- RSPH10B2 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1347171319, COSV51867671; called by muse, mutect2, varscan2
- SARDH | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs201111406, COSV100898374; called by muse, mutect2, varscan2
- SLAMF9 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762469979, COSV63636593; called by muse, mutect2, varscan2
- SLC4A4 | c.1913C>G p.S638* (on ENST00000264485 / NM_001098484.3; = p.S594* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV52624346, COSV99141119; called by muse, mutect2, varscan2
- SNCA | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV100410138; called by muse, mutect2, varscan2
- SYTL1 | c.983C>T p.P328L (on ENST00000543823; = p.P316L on NM_032872.3) | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100539500; called by muse, mutect2, varscan2
- TAF1L | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99645195; called by muse, mutect2
- TAF4B | c.2486G>A p.R829H | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs754468526, COSV52312494; called by muse, mutect2, varscan2
- TBCB | c.618C>G p.G206= | Splice Region (SNP) | VAF 16/152 reads (11%) | catalogued as COSV99696404; called by muse, mutect2, varscan2
- TEX13A | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 36/91 reads (40%) | catalogued as COSV100781757; called by muse, mutect2, varscan2
- TMEM225 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs114104204, COSV66693548; called by muse, mutect2, varscan2
- TNXB | c.5738G>A p.R1913Q (on ENST00000647633; = p.R1666Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.407); catalogued as rs560985106, COSV64472930; called by muse, mutect2, varscan2
- TPR | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100824171, COSV66603580; called by muse, mutect2, varscan2
- ZNF516 | c.2813G>A p.R938Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs996297898, COSV101487343; called by muse, mutect2, varscan2
- ZNF646 | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs200908817, COSV54923038; called by muse, mutect2, varscan2
- ARSK | c.810dup p.E271Rfs*3 | Frame Shift Ins (INS) | VAF 16/53 reads (30%) | called by mutect2, varscan2
- IGBP1P2 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- SYK | c.1413_1415del p.I472del | In Frame Del (DEL) | VAF 14/109 reads (13%) | called by pindel, varscan2
- APOB | c.2610G>A p.Q870= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV99267085; called by muse, mutect2, varscan2
- ARHGEF17 | c.1758C>T p.I586= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV99736390; called by muse, mutect2, varscan2
- ARSB | c.1122C>T p.F374= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as rs149886659; called by muse, mutect2, varscan2
- CELSR2 | c.6039G>A p.E2013= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV54780906; called by muse, mutect2, varscan2
- DBH | c.252C>T p.G84= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs570356950, COSV55041742; called by muse, mutect2, varscan2
- ELOA | c.1311C>G p.L437= | Silent (SNP) | VAF 41/294 reads (14%) | catalogued as COSV101403799, COSV69311265; called by muse, mutect2, varscan2
- EXTL1 | c.1530C>T p.A510= | Silent (SNP) | VAF 27/181 reads (15%) | catalogued as rs1451960870, COSV100958518, COSV65333162; called by muse, mutect2, varscan2
- GRM6 | c.1839G>A p.T613= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs765885831, COSV51440795; called by muse, mutect2, varscan2
- KIAA0100 | c.3681C>T p.V1227= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV101197372; called by muse, mutect2, varscan2
- KIAA0319L | c.3090C>G p.G1030= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV100357588; called by muse, mutect2, varscan2
- LCP2 | c.318G>A p.S106= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs371208606; called by muse, mutect2, varscan2
- LRIG3 | c.2430C>T p.V810= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs375163124; called by muse, mutect2, varscan2
- MMP25 | c.630C>T p.D210= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs146506930; called by muse, mutect2, varscan2
- PDE3A | c.3330G>A p.S1110= | Silent (SNP) | VAF 48/784 reads (6%) | catalogued as rs747690834, COSV62974571; called by muse, mutect2
- PLPPR4 | c.1254G>A p.P418= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs202142961, COSV64564643; called by muse, mutect2, varscan2
- PRKX | c.567G>A p.T189= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs781593197, COSV99468430; called by muse, mutect2, varscan2
- RBM8A | c.198A>T p.P66= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV100355374; called by muse, mutect2, varscan2
- ROCK2 | c.2829G>A p.K943= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV100255696; called by muse, mutect2, varscan2
- SMAD2 | c.180G>A p.E60= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV51011065; called by muse, mutect2, varscan2
- SPPL3 | c.558C>G p.L186= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100793724; called by muse, mutect2, varscan2
- TNS3 | c.4299C>T p.F1433= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs757721376, COSV100235912; called by muse, mutect2, varscan2
- TRIM37 | c.2544G>A p.A848= | Silent (SNP) | VAF 28/182 reads (15%) | catalogued as rs532325984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRMT44 | c.1260C>T p.I420= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs749763146, COSV101077733; called by muse, mutect2, varscan2
- TTN | c.33744A>G p.V11248= (on ENST00000591111; = p.V10321= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/241 reads (19%) | catalogued as COSV100623539; called by muse, mutect2, varscan2
- TUBGCP6 | c.3576T>G p.S1192= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- ZNF345 | c.1446C>T p.C482= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as rs200753949, COSV59323059; called by muse, mutect2, varscan2
- ISG20L2 | c.*1T>G | 3'UTR (SNP) | VAF 50/238 reads (21%) | catalogued as COSV100494075; called by muse, mutect2
